Gene-level copy-number profile of tumor specimen TCGA-3A-A9IB-01A from TCGA case TCGA-3A-A9IB, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.3 years (25,312 days).
Specimen TCGA-3A-A9IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.f9676710-952b-420f-9023-766bc9ed5faf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9IB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e82a04e2-9611-4826-848f-c5c025a66b31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 20,085; copy number 2: 35,931; copy number 3: 3,180; copy number 4: 77; copy number 5: 1; copy number 9: 5; copy number 14: 1; copy number 15: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9IB-01A-21D-A396-01): tumor purity 0.4, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 415 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–2,418,651, 88 genes (within-gene range 0–1) (broad region; genes not listed).
- chr4:181,064,089–187,748,199, 132 genes (broad region; genes not listed).
- chr5:141,136,683–141,512,981, 54 genes (within-gene range 0–2): AC244517.11, PCDHB6, PCDHB17P, AC244517.12, PCDHB7, PCDHB8, AC244517.8, PCDHB16, AC244517.6, AC244517.4, PCDHB9, AC244517.7, PCDHB10, PCDHB11, PCDHB12, PCDHB13, PCDHB14, AC244517.10, PCDHB18P, PCDHB19P, PCDHB15, AC244517.3, TAF7, SLC25A2, AC005618.4, AC005618.1, PCDHGA1, PCDHGA2, PCDHGA3, PCDHGB1, AC005618.3, PCDHGA4, PCDHGB2, PCDHGA5, PCDHGB3, PCDHGA6, PCDHGA7, PCDHGB4, PCDHGA8, PCDHGB5, PCDHGA9, PCDHGB6, PCDHGA10, PCDHGB7, PCDHGA11, PCDHGB8P, AC005618.2, PCDHGA12, PCDHGB9P, AC008781.2, PCDHGC3, RN7SL68P, PCDHGC4, PCDHGC5.
- chr8:150,584–2,165,552, 48 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr8:97,853,021–97,858,947, 2 genes: AP002906.1, SUMO2P18.
- chr18:76,227,990–80,247,514, 91 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:70,605,420–71,827,471, 18 genes, copy number 9–15: AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P.
- chr3:72,006,774–72,084,641, 3 genes, copy number 15: UBE2Q2P9, AC105265.2, AC105265.3.
- chr3:75,964,980–75,965,069, 1 gene, copy number 14: Y_RNA.
- chr8:139,508,701–139,508,971, 1 gene, copy number 5: AC090093.1.

Autosomal genes at a single copy (total copy number 1): 17,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
